Gene-level copy-number profile of specimen HCM-SANG-0293-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0293-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0293-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 02a5866c-59ff-4959-b165-e2f8a2afc1b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0293-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/2f9d2c65-cc5f-4223-bfaf-77ea93d92b7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 21,085; copy number 2: 35,613; copy number 3: 1,572; copy number 4: 25; copy number 5: 80.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,623,806–2,245,605, 2 genes: GMDS, AL035693.1.
- chr6:26,124,145–26,189,112, 7 genes (within-gene range 0–1): H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4.
- chr9:61,330,717–61,666,386, 7 genes: CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–1): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:27,330,827–32,858,120, 80 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
